CGCI case HTMCP-01-01-00004 — HIV+ Tumor Molecular Characterization Project - Diffuse Large B-Cell Lymphoma (CGCI-HTMCP-DLBCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/204ef7a3-ee6e-44f8-985d-5e0c30e4e23c

Demographics
Sex at birth: male; Age at index: 40 years; Vital status: Dead; Days to death: 0 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 40.4 years (14,755 days); Year of diagnosis: 1997; Method of diagnosis: Autopsy; Ann Arbor clinical stage: Stage IV; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: Yes; Days to last follow up: 0 days; Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Mediastinal lymph nodes; Sites of involvement: Gallbladder / Small intestine / Liver / Pancreas, NOS / Lung, NOS / Pleura / Diaphragm.
   Pathology details: Lymph node involved site: Splenic.
   Pathology details: Lymph node involved site: Paraaortic.
   Pathology details: Bone marrow malignant cells: Yes; Lymph node involved site: Mesenteric.
   Treatment given: Treatment intent type: Neoadjuvant; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 0 days; Disease response: With Tumor.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Negative; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Negative; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- CD79A (IHC): Positive.
- IRF4 (IHC): Negative; Specialized molecular test: MUM1 > 30%.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- TP53 (IHC): Negative; Specialized molecular test: P53 > 20%.
- Epstein-Barr Virus (ISH): Negative.

Other clinical attributes
- Comorbidities: HIV/AIDS.
- Risk factors: HIV/AIDS.

Biospecimens (3 samples)
- Sample HTMCP-01-01-00004-01D: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-01-01-00004-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-01-01-00004-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Diffuse large B-cell lymphoma (DLBCL) NOS (any anatomic site nodal or extranodal); History neoadjuvant treatment: Yes; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Lost to follow-up: No.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: para-aortic.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Gallbladder; Submitted tumor site: Small intestine; Submitted tumor site: Liver; Submitted tumor site: Pancreas; Submitted tumor site: Lung; Submitted tumor site: Pleura/Pleural Effusion; Submitted tumor site: Other Extranodal Site.
- Primary pathology: Extranodal involvment other: diaphragm; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: At Autopsy; Lymph nodes examined: Yes; Bone marrow sample histology: Concordant Histology.
- Primary pathology, Pos lymph node locations: Pos lymph node location: Para-aortic.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220629.xlsx, for sample HTMCP-01-01-00004-01D-02D-1353:
- % tumour top: 90
- % tumour bottom: 90

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-DLBCL_biospecimenSupplementSpreadsheet_20220629.xlsx, for sample HTMCP-01-01-00004-11A-02D-1353:
- % tumour top: 0
- % tumour bottom: 0
